CCDI case PBBPKC — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/b7337a5f-d380-4b6c-86e4-e9b2d8eeb7f7

Demographics
Sex at birth: male; Race: white; Vital status: Alive.

Diagnoses (1)
1. Pilocytic astrocytoma: ICD-O-3 morphology code: 9421/1; Tissue or organ of origin: Cerebellum, NOS; Age at diagnosis: 4.7 years (1,708 days).

Biospecimens (3 samples)
- Sample 0DE3GT: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DE3H5: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DE65R: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
